TCGA case TCGA-3H-AB3M — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ebe927e6-0a7e-4c97-ad73-f3c302cca7bc

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Dead; Days to death: 885 days (2.4 years).

Diagnoses (6)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 53.4 years (19,503 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Dasatinib; Days to treatment start: 38 days; Days to treatment end: 66 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Pemetrexed; Days to treatment start: 120 days; Days to treatment end: 386 days (1.1 years); Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Everolimus; Days to treatment start: 120 days; Days to treatment end: 386 days (1.1 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Imatinib; Days to treatment start: 120 days; Days to treatment end: 386 days (1.1 years); Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab + Temsirolimus; Days to treatment start: 471 days (1.3 years); Days to treatment end: 604 days (1.7 years); Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Days to treatment start: 471 days (1.3 years); Days to treatment end: 604 days (1.7 years); Treatment outcome: Stable Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 736 days (2.0 years); Days to treatment end: 800 days (2.2 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement; adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Lung, NOS. Age at diagnosis: 53.7 years (19,610 days); Days to diagnosis: 107 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Lung, NOS. Age at diagnosis: 54.4 years (19,887 days); Days to diagnosis: 384 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
4. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Lung, NOS. Age at diagnosis: 54.6 years (19,945 days); Days to diagnosis: 442 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
5. Progression of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Lung, NOS. Age at diagnosis: 55.4 years (20,227 days); Days to diagnosis: 724 days (2.0 years); Prior treatment: Yes.
   Recorded as not given: Surgery, NOS, for progressive disease.
6. Metastasis of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Abdomen, NOS. Age at diagnosis: 55.6 years (20,325 days); Days to diagnosis: 822 days (2.3 years); Prior treatment: Yes.

Follow-up (8 entries)
- Day 107 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 107 days.
- Day 384 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 384 days (1.1 years).
- Day 442 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 442 days (1.2 years).
- Day 724 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Local; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 724 days (2.0 years).
- Day 822 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Abdomen, NOS; Days to progression: 822 days (2.3 years).
- Days to follow up: 885 days (2.4 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.
- Imaging anatomic site: Pleura; Imaging suv max: 14.2; Timepoint: Prior to Treatment.

Molecular and laboratory tests
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.8; Blood test normal range upper: 1.5].

Exposures
- Exposure type: Asbestos; Exposure source: Occupational.
- Occupation type: General Office Clerks.

Family history
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Ovarian Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3H-AB3M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 160 mg.
  Slide TCGA-3H-AB3M-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3H-AB3M-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3H-AB3M-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Other, please specify; Occupation primary: school district secretary.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 885 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 885 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 107 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3H-AB3M-01A-11D-A39Q-01): tumor purity 0.83, ploidy 1.69, whole-genome doublings 0.
